Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OJ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OJ-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: F

PROCEDURE: SPHS

Reflux and difficulty swallowing. EGD showed Barrett's esophagus and hiatal hernia.

PROCEDURE: SPGD

1. "Distal esophagus and proximal stomach." Received in formalin in a large container is a previously opened 10.6 cm segment of distal esophagus and proximal stomach. Both margins are stapled. The attached perigastric fat is focally hemorrhagic. The adventitia and serosa are unremarkable. The adventitia is inked green in the proximal segment and the distal esophagus is inked black. No ink is applied to the gastric serosa. The segment is 6.9 cm esophagus and 2.4 cm gastric. The esophagogastric junction is diffusely granular and red-tan. The granular mucosa extends up to 3 cm above the EG junction. The proximal esophageal mucosa has two firm lesions. The smaller is 1.2 x 0.8 cm. Its cut surface is gray-tan, homogenous and the maximum thickness is 0.9 cm. This nodular mass extends into the submucosa and focally involves the muscular wall. No penetration to the adventitia is readily seen. This nodular mass is 2.2 cm from the proximal margin. The larger mass is 1.9 x 1.6 x 1.1 cm, red-brown and within 0.6 cm of the proximal margin. Its cut surface is pink-tan, centrally hyperemic and glistening. Penetration to the submucosa is seen with no extension to the muscular wall or adventitia. The gastric mucosa is unremarkable, and there is no evidence of the granular mucosa at the EG junction penetrating into the underlying soft tissue. Lymph node candidates from the perigastric fat are retrieved up to 0.9 cm.

1A-B. Smaller mass and granular esophageal mucosa.

1C-D. Larger mass with granular mucosa.

1E-F. Esophagogastric junction with granular mucosa.

1G. Twelve whole lymph node candidates.

1H. Seven whole lymph node candidates.

Fat retained.

2. "Cervical esophageal margin." Received in formalin in a small container is a 0.5 cm segment of esophagus that is stapled at one margin and open at the opposing margin. The adventitia and mucosa are unremarkable.

2A. Cervical esophageal margin.

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: esophagus, distal third
C15.5

fw
10/9/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: F

PROCEDURE: SPMI

GASTROESOPHAGEAL JUNCTION CARCINOMA
=====

LOCATION: Esophagus, distal.

SIZE: Multifocal (1.2 and 1.9 cm).

TYPE OF CARCINOMA: Adenocarcinoma arising in Barrett's mucosa.

DEPTH OF INVASION: Submucosa (both foci).

HAS IT BEEN TREATED PREOPERATIVELY WITH CHEMO/RADIATION THERAPY: No.

NUMBER OF POSITIVE LYMPH NODES/THE TOTAL NUMBER FOUND: 0/16.

DISTANT METASTASES: Unknown.

RESECTION MARGIN INVOLVED: No.

pT1b N0

PROCEDURE: SPDx

1-2. Esophagus, resection: Multifocal poorly differentiated adenocarcinoma (1.2 and 1.9 cm), arising within Barrett's mucosa with high-grade dysplasia and invading into the submucosa. Margins free. Sixteen lymph nodes negative for malignancy (0/16). Please see TEMPLATE for details.

I, [redacted] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Quasi-Synchronous Primary Noted		

10/9/11

Source: NCI Genomic Data Commons file 0a2fd09b-2386-4745-a3a8-3906e5011ba0 (TCGA-L5-A4OJ.D7476885-7FC7-4EB0-B7AD-E348B5CC171B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).